Somatic mutation profile of tumor specimen 0DIY6A from CCDI case PBBWAH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 4.3 years (1,567 days).
Specimen 0DIY6A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19fba4c5-9d37-4f9e-92ba-3281fed4a8ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY5X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c58ebb28-e8f3-4279-b9c8-f5995ad0b14b

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPX | c.866C>G p.P289R | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NPAS4 | c.1251C>A p.S417R | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2
- TNRC6A | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- B3GAT1 | c.141G>A p.T47= | Silent (SNP) | VAF 45/361 reads (12%) | catalogued as rs374540626; called by muse, mutect2, varscan2
- COL6A6 | c.1008C>G p.A336= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as COSV62041367; called by muse, mutect2
- HOXD9 | c.684A>G p.A228= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- LAMA1 | c.3501G>A p.R1167= | Silent (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- PLA2G7 | c.745T>C p.L249= | Silent (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- H2BC11 | c.*42T>G | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- HBEGF | c.221-82A>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
